TARGET case TARGET-40-PAKXLD — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20768995-afe7-52c5-b305-1fae8253fb88

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 14 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.0; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 14.4 years (5,245 days); Year of diagnosis: 2001; Metastasis at diagnosis: No Metastasis; Days to last follow up: 2,462 days (6.7 years).
   Pathology details: Necrosis percent: 30.
   Treatment given: Protocol identifier: P9754.

Follow-up (2 entries)
- Days to follow up: 578 days (1.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 578 days (1.6 years); Days to first event: 578 days (1.6 years); First event: Relapse.
- Days to follow up: 2,462 days (6.7 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2008.

Biospecimens (2 samples)
- Sample TARGET-40-PAKXLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PAKXLD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2462
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Arm/hand
- Specific tumor site: Humerus
- Specific tumor region: Proximal
- Primary site progression: Yes
- Site of initial relapse: Lung

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAKXLD-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 97
- % Non Tumor Nuclei: Top from Biopsy: 3
- % Cellular Tumor: Top from Biopsy: 90
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 1
- % Necrosis: Top from Biopsy: 9
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 94
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 1
- % Necrosis: Bottom from Biopsy: 5
- PASS/FAIL: pass
